Somatic mutation profile of tumor specimen 0DJIM2 from CCDI case PBBWTE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,113 days).
Specimen 0DJIM2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46a0414d-420d-4dab-ba81-ab7c073612c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/402f08e3-9b02-403f-bb6d-b865c16fe370

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/507 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTSL3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs754672935, COSV54439444; called by muse, mutect2, varscan2
- ACBD3 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CCNB3 | c.3500G>T p.W1167L | Missense Mutation (SNP) | VAF 139/510 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RAB11FIP1 | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.082); called by muse, mutect2
- RANGRF | c.438-74G>A | Intron (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- SMARCD3 | c.580-25C>T | Intron (SNP) | VAF 88/308 reads (29%) | catalogued as rs781013031; called by muse, mutect2, varscan2
